Somatic mutation profile of tumor specimen C3L-09191-01 (aliquot CPT0499390007) from CPTAC case C3L-09191, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 32.1 years (11,708 days).
Specimen C3L-09191-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8c57fe4-5c81-422c-980d-560204cf778f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-09191-31 (Blood Derived Normal), aliquot CPT0499480002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ab418c1-07ca-469b-b529-c76dbb5a1b7b

The open-access MAF lists 57 somatic variants for this specimen: 43 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 13, Nonstop Mutation 1, Nonsense Mutation 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALKBH6 | c.547G>T p.G183C (on ENST00000252984 / NM_001297701.2; = p.G211C on NM_032878.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/631 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs538782058; called by muse, mutect2
- CSMD3 | c.9996A>C p.Q3332H (on ENST00000297405 / NM_001363185.1; = p.Q3163H on NM_052900.3) | Missense Mutation (SNP) | VAF 45/550 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV52177216, COSV99820985; called by muse, mutect2
- CUBN | c.7136T>A p.F2379Y | Missense Mutation (SNP) | VAF 43/365 reads (12%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.529); catalogued as COSV100913706; called by muse, mutect2, varscan2
- DNAH5 | c.12599A>C p.K4200T | Missense Mutation (SNP) | VAF 56/501 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54201514, COSV54202045, COSV54212456; called by muse, mutect2, varscan2
- IDH3B | c.922C>T p.R308W | Missense Mutation (SNP) | VAF 24/368 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs753278957; called by muse, mutect2
- KIF27 | c.1664T>G p.L555R | Missense Mutation (SNP) | VAF 37/351 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV52825178; called by muse, mutect2, varscan2
- MUC16 | c.7148T>C p.M2383T | Missense Mutation (SNP) | VAF 48/348 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.402); catalogued as rs1308028611; called by muse, mutect2, varscan2
- MYBPC3 | c.3788G>C p.R1263P | Missense Mutation (SNP) | VAF 35/411 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as rs781180230, COSV57030358; called by muse, mutect2
- NECAB3 | c.1133C>T p.P378L (on ENST00000246190 / NM_031232.4; = p.P344L on NM_031231.4) | Missense Mutation (SNP) | VAF 15/500 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1295333268; called by muse, mutect2
- OPCML | c.401T>G p.V134G | Missense Mutation (SNP) | VAF 24/222 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as COSV100101285; called by mutect2, varscan2
- OR11H12 | c.809T>G p.L270R | Missense Mutation (SNP) | VAF 36/828 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1339564423; called by muse, mutect2
- OR51F1 | c.506T>G p.L169R | Missense Mutation (SNP) | VAF 40/371 reads (11%) | SIFT tolerated (0.35); PolyPhen probably damaging (1); catalogued as COSV100598875, COSV58578784; called by muse, mutect2, varscan2
- PEX5L | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 24/311 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as rs374485695; called by muse, mutect2
- PKD1 | c.11249G>C p.R3750P (on ENST00000262304 / NM_001009944.3; = p.R3749P on NM_000296.4) | Missense Mutation (SNP) | VAF 30/436 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM109266; called by muse, mutect2
- PTPRC | c.1756C>A p.L586M | Missense Mutation (SNP) | VAF 55/326 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV61406557; called by muse, mutect2, varscan2
- SCML2 | c.1645C>G p.L549V | Missense Mutation (SNP) | VAF 39/526 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as rs1422512820; called by muse, mutect2
- TRIM49C | c.979A>C p.S327R | Missense Mutation (SNP) | VAF 32/442 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.028); catalogued as COSV71510527, COSV71511634; called by muse, mutect2
- WNT2B | c.1042C>T p.R348* (on ENST00000369684 / NM_024494.3; = p.R329* on NM_004185.4) | Nonsense Mutation (SNP) | VAF 35/578 reads (6%) | catalogued as rs751293359, COSV56677311; called by muse, mutect2
- ZNF135 | c.658G>A p.G220R (on ENST00000313434 / NM_001289401.2; = p.G232R on NM_003436.4) | Missense Mutation (SNP) | VAF 63/520 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.106); catalogued as rs374589646, COSV57881715; called by muse, mutect2, varscan2
- ZNF140 | c.1186C>T p.R396W | Missense Mutation (SNP) | VAF 35/346 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as rs761496710; called by muse, mutect2, varscan2
- ABCA12 | c.721A>T p.I241L | Missense Mutation (SNP) | VAF 47/373 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACKR1 | c.695A>C p.K232T | Missense Mutation (SNP) | VAF 94/533 reads (18%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- ACVR2A | c.264-1G>A p.X88_splice | Splice Site (SNP) | VAF 45/203 reads (22%) | called by muse, mutect2, varscan2
- BCL10 | c.702A>G p.*234Wext*6 | Nonstop Mutation (SNP) | VAF 35/277 reads (13%) | called by muse, mutect2, varscan2
- GABRA1 | c.971T>C p.V324A | Missense Mutation (SNP) | VAF 44/538 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2
- HAS1 | c.1312G>A p.V438M | Missense Mutation (SNP) | VAF 41/638 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.194); called by muse, mutect2
- HDAC6 | c.1313T>C p.L438P | Missense Mutation (SNP) | VAF 36/468 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- IZUMO3 | c.686A>T p.E229V (on ENST00000543880 / NM_001365008.2; = p.E223V on NM_001271706.1) | Missense Mutation (SNP) | VAF 32/287 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- KRTAP6-2 | c.142T>G p.F48V | Missense Mutation (SNP) | VAF 37/317 reads (12%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- LRFN5 | c.971A>C p.E324A | Missense Mutation (SNP) | VAF 54/426 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- LRP1B | c.13024A>G p.S4342G | Missense Mutation (SNP) | VAF 86/379 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- NUP153 | c.1088C>G p.P363R | Missense Mutation (SNP) | VAF 14/393 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR8J2 | c.230T>G p.V77G | Missense Mutation (SNP) | VAF 37/301 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.274); called by muse, mutect2, varscan2
- PIWIL2 | c.1455G>T p.M485I | Missense Mutation (SNP) | VAF 46/356 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PXDNL | c.3794A>G p.Q1265R | Missense Mutation (SNP) | VAF 36/614 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0.001); called by muse, mutect2
- RCBTB1 | c.1175G>A p.C392Y | Missense Mutation (SNP) | VAF 14/199 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- SATL1 | c.658A>C p.S220R (on ENST00000395409; = p.S407R on NM_001012980.2) | Missense Mutation (SNP) | VAF 54/667 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.854); called by muse, mutect2
- SKIV2L | c.650C>T p.P217L | Missense Mutation (SNP) | VAF 42/515 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.045); called by muse, mutect2
- VEGFC | c.737A>T p.N246I | Missense Mutation (SNP) | VAF 49/342 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- ZMYM3 | c.890C>T p.S297L | Missense Mutation (SNP) | VAF 58/686 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2
- ZNF17 | c.1813A>G p.T605A | Missense Mutation (SNP) | VAF 50/537 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.011); called by muse, mutect2
- ZNF804A | c.578A>T p.Y193F | Missense Mutation (SNP) | VAF 59/371 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZP4 | c.854G>T p.C285F | Missense Mutation (SNP) | VAF 42/304 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCC8 | c.4227C>T p.I1409= | Silent (SNP) | VAF 41/444 reads (9%) | catalogued as rs146584228; ClinVar: likely benign; called by muse, mutect2
- ADARB2 | c.777C>T p.R259= | Silent (SNP) | VAF 36/368 reads (10%) | catalogued as COSV67225179; called by muse, mutect2
- BPIFB2 | c.144C>T p.A48= | Silent (SNP) | VAF 42/454 reads (9%) | called by muse, mutect2
- FLRT2 | c.816C>T p.F272= | Silent (SNP) | VAF 39/409 reads (10%) | called by muse, mutect2
- GRIN2C | c.1284C>T p.P428= | Silent (SNP) | VAF 79/511 reads (15%) | catalogued as rs949361839; called by muse, mutect2, varscan2
- KIAA1210 | c.3798G>C p.G1266= | Silent (SNP) | VAF 39/530 reads (7%) | called by muse, mutect2
- MLXIP | c.1524G>A p.V508= | Silent (SNP) | VAF 50/562 reads (9%) | called by muse, mutect2
- OR12D2 | c.870T>C p.T290= | Silent (SNP) | VAF 54/583 reads (9%) | called by muse, mutect2
- PCYOX1 | c.1113A>G p.L371= | Silent (SNP) | VAF 55/330 reads (17%) | called by muse, mutect2, varscan2
- PEG3 | c.4578T>G p.T1526= | Silent (SNP) | VAF 39/382 reads (10%) | catalogued as COSV55626937, COSV55641370; called by muse, mutect2, varscan2
- RBMXL1 | c.78A>C p.T26= | Silent (SNP) | VAF 36/826 reads (4%) | called by muse, mutect2
- TOMM20L | c.99G>C p.R33= | Silent (SNP) | VAF 20/320 reads (6%) | called by muse, mutect2
- WDFY4 | c.5871T>C p.S1957= | Silent (SNP) | VAF 44/535 reads (8%) | called by muse, mutect2
- SSX5 | c.69+175A>C | Intron (SNP) | VAF 36/386 reads (9%) | catalogued as rs782397307, COSV61254692; called by muse, mutect2
